Somatic mutation profile of tumor specimen ALCH-AFF4-TTP1-A (aliquot ALCH-AFF4-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AFF4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.8 years (22,555 days).
Specimen ALCH-AFF4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea994cd6-0fdd-4d7e-91ae-dc586b915e81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFF4-NB1-A (Blood Derived Normal), aliquot ALCH-AFF4-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/733d7ef0-a066-4d95-9b84-34a32aadd284

The open-access MAF lists 823 somatic variants for this specimen: 577 protein-altering or splice-affecting, 165 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 484, Silent 165, Nonsense Mutation 48, Intron 39, RNA 23, Splice Site 16, Frame Shift Del 15, 3'UTR 9, 5'UTR 7, Frame Shift Ins 5, Splice Region 5, Translation Start Site 2.

Variants (750 of 823; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.2320G>C p.G774R | Missense Mutation (SNP) | VAF 71/425 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569681869, CM072959; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 119/578 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs397507520, CM021131, CM021132, COSV61007093, COSV61009400; ClinVar: pathogenic; called by muse, mutect2
- AADACL3 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs748441437; called by muse, mutect2, varscan2
- ABCA2 | c.754C>G p.L252V (on ENST00000614293; = p.L222V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.03); catalogued as rs1449979402; called by muse, mutect2, varscan2
- AC005833.1 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious, low confidence (0); catalogued as rs756501168; called by muse, varscan2
- AC011005.1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs552758585, COSV71956069; called by muse, mutect2, varscan2
- ACHE | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574646; called by muse, mutect2, varscan2
- ACO1 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59385282; called by muse, mutect2, varscan2
- ADAMDEC1 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 47/371 reads (13%) | catalogued as COSV56477089; called by muse, mutect2, varscan2
- ADAMTS16 | c.2633G>C p.R878P | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.758); catalogued as COSV99940809; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4564G>T p.V1522L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs201111545, COSV99716839; called by muse, mutect2
- AFF2 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1359721857, COSV53992826; called by muse, mutect2, varscan2
- AGBL1 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV101407941; called by muse, mutect2, varscan2
- ALB | c.1289+1G>T p.X430_splice | Splice Site (SNP) | VAF 36/520 reads (7%) | catalogued as CS122001, COSV55735420, COSV55742076; called by muse, mutect2
- ANO2 | c.2164C>T p.H722Y (on ENST00000356134 / NM_001278597.3; = p.H726Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs752700191; called by mutect2, varscan2
- ARHGAP31 | c.348G>A p.T116= | Splice Region (SNP) | VAF 26/274 reads (9%) | catalogued as rs749601853, COSV99956942; called by muse, mutect2
- ARHGEF25 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV54087472, COSV99677853; called by muse, mutect2
- ARMC4 | c.2122del p.D708Tfs*25 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as COSV100536672, COSV59461933; called by mutect2, pindel
- ATP2A3 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV59230815; called by muse, mutect2
- ATP2B3 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99684916; called by muse, mutect2, varscan2
- BAIAP2L2 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1004221703; called by muse, mutect2
- BCORL1 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99498849; called by muse, mutect2, varscan2
- BMPR1B | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 30/499 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV99215445; called by muse, mutect2
- BRINP2 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV64179587; called by muse, mutect2
- BTD | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374141881; called by muse, mutect2
- C10orf71 | c.4049G>T p.R1350L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60506726; called by muse, mutect2, varscan2
- C12orf54 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs146567743; called by muse, mutect2, varscan2
- CABS1 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV56732995, COSV56733238; called by muse, mutect2
- CCL24 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.082); catalogued as rs782346041; called by muse, mutect2, varscan2
- CCT8L2 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs1327260596, COSV63464036; called by muse, mutect2
- CD300E | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs150917118; called by muse, mutect2, varscan2
- CDH10 | c.2183C>A p.P728H | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52604247; called by muse, mutect2, varscan2
- CDH9 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50251915; called by muse, varscan2
- CDK5RAP3 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58115968; called by muse, mutect2, varscan2
- CHL1 | c.3071G>C p.G1024A (on ENST00000397491 / NM_001253387.1; = p.G1040A on NM_006614.4) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775076666; called by muse, mutect2, varscan2
- CLCN1 | c.2828C>A p.A943D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.476); catalogued as rs1366723815; called by muse, mutect2, varscan2
- COL11A2 | c.1304G>C p.G435A (on ENST00000341947 / NM_080680.3; = p.G328A on NM_080679.2) | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100553868; called by muse, mutect2, varscan2
- COL1A2 | c.3363G>T p.Q1121H | Missense Mutation (SNP) | VAF 31/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51955681; called by muse, mutect2
- COL26A1 | c.1252G>T p.D418Y (on ENST00000313669 / NM_001278563.3; = p.D416Y on NM_133457.4) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as rs374237766, COSV100561810; called by muse, mutect2, varscan2
- COL2A1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1198767080; called by muse, mutect2, varscan2
- COL4A5 | c.4624C>A p.P1542T | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV60367663; called by muse, mutect2, varscan2
- COLGALT2 | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100730328; called by muse, mutect2, varscan2
- CPED1 | c.2821C>G p.R941G | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60009189; called by muse, mutect2, varscan2
- CPXCR1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV52160897, COSV52160966; called by muse, mutect2, varscan2
- CSF2RA | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV62626576; called by muse, mutect2
- CSMD3 | c.10973C>A p.P3658H (on ENST00000297405 / NM_001363185.1; = p.P3489H on NM_052900.3) | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99836384; called by muse, mutect2
- CSMD3 | c.6003C>G p.N2001K (on ENST00000297405 / NM_001363185.1; = p.N1897K on NM_052900.3) | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.464); catalogued as rs761767871; called by muse, mutect2
- CSMD3 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52263123; called by muse, mutect2
- DAB2 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV57915340; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs754135731; called by mutect2, varscan2*
- DYNC1I1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 82/651 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs756345512, COSV61474207; called by muse, mutect2, varscan2
- ESYT2 | c.1051A>G p.I351V (on ENST00000613624; = p.I275V on NM_020728.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99276542; called by muse, mutect2, varscan2
- EYS | c.7171G>T p.G2391* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV65494609; called by muse, mutect2, varscan2
- FAT1 | c.8989A>T p.T2997S | Missense Mutation (SNP) | VAF 48/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376371650; called by muse, mutect2
- FCAR | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV62031866; called by muse, mutect2
- FCRL2 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as COSV63834130; called by muse, mutect2, varscan2
- FFAR1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1456826776; called by muse, mutect2, varscan2
- FHL5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV58739037; called by muse, mutect2, varscan2
- FLOT2 | c.1234G>T p.V412L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs201936801; called by muse, mutect2, varscan2
- FOXRED2 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1414594769; called by muse, mutect2
- GABRA5 | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV59476890; called by muse, mutect2
- GAD2 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs1311625272; called by muse, mutect2, varscan2
- GIMAP4 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV55432712; called by muse, mutect2, varscan2
- HIVEP1 | c.8029G>T p.G2677C | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV65104170; called by muse, mutect2, varscan2
- HMCN1 | c.2860G>T p.D954Y | Missense Mutation (SNP) | VAF 104/648 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99623548; called by muse, varscan2
- HTR5A | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55281263; called by muse, mutect2, varscan2
- IGLON5 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54537855; called by muse, mutect2, varscan2
- IGLV1-40 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as rs750661603; called by muse, mutect2
- INSYN2B | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953442; called by muse, mutect2
- ITIH5 | c.1529C>A p.S510* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV53667736; called by muse, mutect2, varscan2
- KANK3 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs1178124998; called by muse, varscan2
- KCNB1 | c.2249C>A p.A750E | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.141); catalogued as COSV65566603; called by muse, mutect2, varscan2
- KCNG1 | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.914); catalogued as rs762824131, COSV100857087, COSV100857088; called by mutect2, varscan2
- KCNH4 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV52917377; called by muse, mutect2, varscan2
- KCNJ5 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57964191, COSV57969287; called by muse, mutect2, varscan2
- KIF2B | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143310670; called by muse, mutect2, varscan2
- KIR2DS4 | c.318C>A p.H106Q | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.296); catalogued as rs1303213812; called by muse, mutect2
- KLK8 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV99143936; called by muse, mutect2
- KRT31 | c.1092C>A p.D364E | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV52434351; called by muse, varscan2
- KRTAP10-9 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100552859; called by muse, mutect2
- KRTAP13-4 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | catalogued as COSV100481823; called by muse, mutect2
- LAIR2 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56620779; called by muse, mutect2, varscan2
- LAMA2 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 53/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150586612, COSV70338895; called by muse, mutect2, varscan2
- LAMA3 | c.3581C>T p.P1194L | Missense Mutation (SNP) | VAF 80/591 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs370400316; called by muse, mutect2, varscan2
- LAMB4 | c.993G>C p.S331= | Splice Region (SNP) | VAF 3/30 reads (10%) | catalogued as rs1442234562, COSV99224188; called by muse, mutect2
- LHFPL3 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.292); catalogued as COSV67810129; called by muse, mutect2, varscan2
- LRRC15 | c.1526C>A p.T509N | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV61650314; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LSM14A | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101471750, COSV70884669; called by muse, mutect2, varscan2
- MAGEC2 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1319299913; called by muse, mutect2, varscan2
- MAP2 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 54/255 reads (21%) | catalogued as COSV52295573, COSV52313711; called by muse, mutect2, varscan2
- MAPK8IP1 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770034894, COSV53797131; called by muse, mutect2
- MATR3 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 50/440 reads (11%) | catalogued as COSV100735238; called by muse, mutect2, varscan2
- MGA | c.8687C>T p.S2896F (on ENST00000219905 / NM_001164273.1; = p.S2687F on NM_001080541.2) | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV54956666; called by muse, mutect2, varscan2
- MKRN3 | c.986T>A p.F329Y | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100090875; called by muse, mutect2
- MPZL1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 51/391 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776240326; called by muse, mutect2, varscan2
- MROH1 | c.4240G>C p.D1414H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58192930; called by muse, mutect2
- MVB12B | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.542); catalogued as rs1219015533; called by muse, mutect2, varscan2
- MYH6 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 36/335 reads (11%) | catalogued as rs1192749008, COSV62453690; called by muse, mutect2, varscan2
- MYH8 | c.3225C>A p.D1075E | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV67959259; called by muse, mutect2
- NAV3 | c.3224C>A p.S1075* | Nonsense Mutation (SNP) | VAF 41/274 reads (15%) | catalogued as COSV57076442; called by muse, mutect2, varscan2
- NBEAL1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205971498; called by muse, mutect2, varscan2
- NEXMIF | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV50021711; called by muse, mutect2, varscan2
- NLGN1 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 50/692 reads (7%) | catalogued as COSV64342080; called by muse, mutect2
- NLRP13 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV99048648; called by muse, mutect2, varscan2
- NLRP4 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774131244, COSV56718987; called by muse, mutect2, varscan2
- NPAP1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100275971, COSV104413159; called by muse, mutect2
- NPFFR2 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58145794; called by muse, mutect2
- NPHP3 | c.3020T>C p.L1007P | Missense Mutation (SNP) | VAF 43/644 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM139044; called by muse, mutect2
- NSUN6 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs144268180; called by muse, mutect2
- NTNG1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV53990273; called by muse, mutect2, varscan2
- NXF3 | c.886A>C p.I296L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs1392081828; called by muse, varscan2
- OPCML | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV59443310; called by muse, varscan2
- OPLAH | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782261105; called by muse, mutect2, varscan2
- OR2A2 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs150058768, COSV68872182; called by muse, mutect2
- OR4D10 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866207750; called by muse, mutect2, varscan2
- OR52K2 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as COSV57835132; called by muse, mutect2, varscan2
- OR5H1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 84/673 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV100641623, COSV100641667; called by muse, mutect2, varscan2
- OR9Q1 | c.447C>G p.Y149* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV59041921; called by muse, mutect2
- P2RX3 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as COSV54442659; called by muse, mutect2, varscan2
- P3H3 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555122407; called by muse, mutect2, varscan2
- PAPPA2 | c.2576C>A p.S859Y | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1383613255, COSV62772081; called by muse, mutect2, varscan2
- PCDHA6 | c.1389C>A p.F463L | Missense Mutation (SNP) | VAF 76/523 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.42); catalogued as COSV65343220; called by muse, mutect2, varscan2
- PCDHB15 | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.081); catalogued as rs147410183, COSV50872050; called by muse, mutect2, varscan2
- PCDHGA2 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs377098882; called by muse, mutect2
- PDE4DIP | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs782578310, COSV100515665; called by muse, mutect2, varscan2
- PHGDH | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 107/552 reads (19%) | catalogued as rs11555912; called by muse, mutect2, varscan2
- PLEKHA4 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52339553; called by muse, mutect2, varscan2
- PLXNB3 | c.5359G>C p.A1787P | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737402; called by muse, mutect2, varscan2
- PNCK | c.240C>A p.H80Q (on ENST00000340888 / NM_001366975.1; = p.H163Q on NM_001039582.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61743385; called by muse, mutect2, varscan2
- POGLUT3 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs17853654; called by muse, mutect2, varscan2
- POLQ | c.5722G>T p.G1908C | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51764843; called by muse, mutect2
- POTED | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV55047561; called by muse, mutect2
- PPP1R3F | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV50020327; called by muse, mutect2, varscan2
- PRKG2 | c.1522C>A p.L508M | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV52320059; called by muse, mutect2, varscan2
- PRKN | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as CM103387, COSV58223059; called by muse, mutect2, varscan2
- PROKR2 | c.279del p.N94Tfs*68 | Frame Shift Del (DEL) | VAF 37/347 reads (11%) | catalogued as COSV54086423, COSV99450604; called by mutect2, pindel, varscan2
- PSIP1 | c.149+1G>T p.X50_splice | Splice Site (SNP) | VAF 31/213 reads (15%) | catalogued as COSV66255392, COSV66255775; called by muse, mutect2, varscan2
- PSMB11 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs749759351; called by muse, mutect2, varscan2
- PXDNL | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 54/674 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761583823, COSV62498079; called by muse, mutect2
- RBMX | c.4G>T p.V2F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs765673292; called by mutect2, varscan2
- RNF13 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV60135641; called by muse, mutect2
- RPS6KC1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873753; called by muse, mutect2, varscan2
- RPTN | c.1151C>A p.T384K | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60168191; called by muse, mutect2, varscan2
- RYR1 | c.4690G>T p.E1564* | Nonsense Mutation (SNP) | VAF 41/403 reads (10%) | catalogued as COSV100617167, COSV62093753; called by muse, mutect2, varscan2
- SALL1 | c.3568C>A p.P1190T | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747967468; called by muse, mutect2, varscan2
- SALL1 | c.2890C>A p.P964T | Missense Mutation (SNP) | VAF 88/562 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51762964; called by muse, mutect2, varscan2
- SASH1 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.59); catalogued as rs868824013, COSV66567816; called by muse, mutect2, varscan2
- SEM1 | c.171G>T p.R57= | Splice Region (SNP) | VAF 26/267 reads (10%) | catalogued as COSV69740004; called by muse, mutect2
- SERPINB11 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 35/477 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.153); catalogued as rs1201039883; called by muse, mutect2
- SERPINB13 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV54031097; called by muse, mutect2
- SGIP1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52772821, COSV52774593; called by muse, mutect2, varscan2
- SHOX | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | catalogued as CM074529; called by muse, mutect2
- SIGLEC1 | c.2018G>T p.R673L | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs754799562, COSV52472611; called by muse, mutect2
- SLC22A24 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751000536; called by muse, mutect2, varscan2
- SLC25A46 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1290028638; called by muse, varscan2
- SLC30A10 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV63075506; called by muse, mutect2
- SLC30A8 | c.1074C>A p.D358E | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.036); catalogued as COSV69972279; called by muse, mutect2
- SLC5A12 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54819343; called by muse, mutect2, varscan2
- SLC9A4 | c.599del p.G200Afs*3 | Frame Shift Del (DEL) | VAF 41/286 reads (14%) | catalogued as COSV54828632; called by mutect2, pindel, varscan2
- SLITRK4 | c.2386G>T p.G796C | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV62025982; called by muse, mutect2, varscan2
- SLTM | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51053969; called by muse, mutect2, varscan2
- SPDYC | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65865338; called by muse, mutect2
- SPSB4 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60150694; called by muse, mutect2
- SSMEM1 | c.621C>A p.N207K | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.286); catalogued as COSV52833053; called by muse, mutect2, varscan2
- ST18 | c.849C>G p.S283R | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52487499, COSV99390014; called by muse, mutect2
- STC1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs758995378, COSV51689073; called by muse, mutect2, varscan2
- TBX22 | c.702C>G p.D234E | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.164); catalogued as rs774836026; called by muse, mutect2, varscan2
- TCEAL2 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 77/211 reads (36%) | catalogued as COSV61197257, COSV61197513; called by muse, mutect2, varscan2
- TM4SF20 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs369026166; called by muse, mutect2, varscan2
- TMC3 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs759090667; called by muse, mutect2, varscan2
- TMEM132D | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67159575; called by muse, mutect2, varscan2
- TMPRSS5 | c.1139A>T p.Y380F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55427736; called by muse, mutect2
- TRABD2A | c.1322G>T p.R441L (on ENST00000409520 / NM_001277053.2; = p.R392L on NM_001080824.3) | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs377499574, COSV52884091; called by muse, mutect2, varscan2
- TRO | c.1108T>A p.S370T | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99055800; called by muse, mutect2, varscan2
- TTC21A | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.23); catalogued as COSV57185273; called by muse, mutect2
- TTC28 | c.7151C>T p.T2384M | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.197); catalogued as rs867852342; called by muse, mutect2
- TTLL8 | c.1519A>T p.M507L | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs764354988; called by muse, mutect2, varscan2
- URB1 | c.5515G>A p.A1839T | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1239649464; called by muse, mutect2, varscan2
- VPS33A | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57359186; called by muse, mutect2, varscan2
- VSTM2B | c.734del p.G245Dfs*29 | Frame Shift Del (DEL) | VAF 25/172 reads (15%) | catalogued as COSV59263061; called by mutect2, pindel, varscan2
- WDR5B | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51657300; called by muse, mutect2
- XIRP1 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs199532332; called by muse, mutect2
- ZDHHC1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775156668; called by muse, mutect2, varscan2
- ZFHX4 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 24/436 reads (6%) | catalogued as COSV51490301; called by muse, mutect2
- ZGRF1 | c.5733G>T p.W1911C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1274098782; called by muse, mutect2, varscan2
- ZIC1 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51551824, COSV51558768; called by muse, mutect2
- ZNF136 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1401197714; called by muse, mutect2, varscan2
- ZNF716 | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV70779837; called by muse, mutect2, varscan2
- ZNF804B | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 46/382 reads (12%) | catalogued as COSV60817760; called by muse, varscan2
- ZNF98 | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV63340603; called by muse, mutect2, varscan2
- ZNF99 | c.129G>T p.L43= | Splice Region (SNP) | VAF 28/199 reads (14%) | catalogued as COSV68056209, COSV99078016; called by muse, mutect2, varscan2
- ABCA8 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AC100868.1 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTL6B | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- ACTN2 | c.1867C>A p.Q623K | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTS16 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 50/479 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- ADAMTS18 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS19 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY4 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADGRG4 | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.217); called by muse, varscan2
- ADGRL2 | c.2666A>G p.N889S (on ENST00000370717 / NM_001366005.1; = p.N876S on NM_012302.4) | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- AHNAK2 | c.7991G>T p.G2664V | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AKAP12 | c.2852C>A p.T951N | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- AKAP9 | c.4656G>T p.M1552I | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKNAD1 | c.1457C>A p.T486N | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ANK2 | c.6566C>T p.P2189L | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- APBB2 | c.1704T>G p.N568K (on ENST00000295974 / NM_001166050.2; = p.N569K on NM_004307.2) | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2
- AQP10 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AQP4 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 30/842 reads (4%) | called by muse, mutect2
- ARF5 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2
- ARFGEF3 | c.4409G>T p.R1470L | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGAP20 | c.3068G>A p.W1023* | Nonsense Mutation (SNP) | VAF 24/283 reads (8%) | called by muse, mutect2
- ARHGEF33 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB5 | c.963A>T p.L321F | Missense Mutation (SNP) | VAF 34/401 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, mutect2
- ASIC4 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ATF1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATP10B | c.2580G>T p.E860D | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ATP13A1 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP13A3 | c.2875-2A>T p.X959_splice | Splice Site (SNP) | VAF 42/357 reads (12%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2902G>T p.A968S (on ENST00000545399 / NM_001256214.2; = p.A955S on NM_152296.5) | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ATP2B2 | c.1439G>T p.G480V (on ENST00000352432; = p.G446V on NM_001683.5) | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- BBS9 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 94/776 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- BMP7 | c.1266C>A p.N422K | Missense Mutation (SNP) | VAF 52/535 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- BTD | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); called by muse, mutect2
- BUB1B | c.1027T>A p.Y343N | Missense Mutation (SNP) | VAF 65/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C6orf141 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- CACNA1H | c.3363+1G>T p.X1121_splice | Splice Site (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2, varscan2
- CACNA1S | c.5035C>A p.H1679N | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D4 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK2D | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMSAP1 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CARD9 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CAV1 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCDC141 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CCDC168 | c.7607A>T p.Y2536F | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.042); called by muse, mutect2
- CCDC168 | c.5255G>T p.G1752V | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC83 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD163 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- CD1D | c.6del p.C3_?2 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.3787G>T p.G1263C | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CDYL2 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPE | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CEP41 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP161 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP61 | c.82A>T p.K28* | Nonsense Mutation (SNP) | VAF 34/340 reads (10%) | called by muse, mutect2, varscan2
- CFAP77 | c.254A>C p.Q85P | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CFH | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 21/526 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CFP | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CHD1 | c.4006G>T p.A1336S | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- CHORDC1 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHRM2 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 75/518 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CMYA5 | c.11542G>T p.G3848* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- COL20A1 | c.2680C>A p.P894T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL25A1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- COL27A1 | c.5366G>T p.R1789L | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- COL9A2 | c.30C>G p.S10R | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL9A3 | c.792+2T>A p.X264_splice | Splice Site (SNP) | VAF 24/295 reads (8%) | called by muse, mutect2
- CPNE5 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CPVL | c.687C>A p.N229K | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2
- CR1 | c.5059G>T p.G1687W | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CRYBG3 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CSMD1 | c.5630C>A p.T1877K (on ENST00000520002; = p.T1876K on NM_033225.6) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNND2 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CTSG | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTSG | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- CXCR4 | c.980A>T p.K327M | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CYP1B1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CYRIA | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CYTIP | c.837T>A p.S279R | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DCAF4L1 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); called by muse, mutect2
- DCAF4L2 | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DCP1B | c.1613C>A p.P538Q | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DHDH | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DMAC1 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.9583C>A p.Q3195K | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); called by muse, mutect2
- DOCK1 | c.2828A>T p.E943V | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- DROSHA | c.1116G>T p.W372C | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DSCAM | c.1621T>A p.S541T | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); called by muse, mutect2
- DST | c.13351G>T p.A4451S (on ENST00000361203 / NM_001374722.1; = p.A2039S on NM_015548.5) | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DYNC2H1 | c.11990G>C p.G3997A | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DYNC2LI1 | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- EBF3 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- ECE2 | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECHDC2 | c.252T>A p.S84R | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EHHADH | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3L | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ELAPOR2 | c.1736G>T p.R579I (on ENST00000450689 / NM_001142749.3; = p.R412I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ELFN1 | c.1256T>C p.I419T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ELOA2 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- EYA4 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 50/497 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EYS | c.6920G>T p.G2307V | Missense Mutation (SNP) | VAF 73/633 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM71A | c.248C>A p.P83Q | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FARSA | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.1079-1G>T p.X360_splice | Splice Site (SNP) | VAF 34/388 reads (9%) | called by muse, mutect2
- FBXO3 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 43/548 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2
- FBXO39 | c.940A>T p.R314* | Nonsense Mutation (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- FBXO42 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FBXO42 | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 60/289 reads (21%) | called by muse, mutect2, varscan2
- FCGBP | c.2505C>A p.C835* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- FCGBP | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGF20 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FHAD1 | c.3855G>C p.R1285S | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FLCN | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.077); called by muse, mutect2
- FMO2 | c.401dup p.E135Gfs*7 | Frame Shift Ins (INS) | VAF 48/272 reads (18%) | called by mutect2, pindel, varscan2
- FREM2 | c.8966G>C p.G2989A | Missense Mutation (SNP) | VAF 60/650 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- FSCN3 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- FSIP2 | c.4708A>T p.T1570S | Missense Mutation (SNP) | VAF 76/367 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRR3 | c.812T>G p.V271G | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- GDF5 | c.1283A>T p.H428L | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- GHR | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 95/887 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GLRB | c.1477dup p.W493Lfs*38 | Frame Shift Ins (INS) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- GMPS | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GNA13 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNG13 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLGA8K | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- GPX6 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- GRIN2A | c.669C>G p.H223Q | Missense Mutation (SNP) | VAF 78/568 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRM7 | c.828C>G p.D276E | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- H3C4 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 46/558 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); called by muse, mutect2
- HIVEP1 | c.3797G>A p.S1266N | Missense Mutation (SNP) | VAF 98/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.11787C>A p.H3929Q | Missense Mutation (SNP) | VAF 123/653 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); called by muse, varscan2
- HORMAD2 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- HTATSF1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- IFRD2 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFT172 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHMBP2 | c.1661A>T p.H554L | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- IGKV3D-7 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 34/349 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IL24 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- IL36B | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ILDR2 | c.380-1G>T p.X127_splice | Splice Site (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- IRAG1 | c.2515C>A p.H839N | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRAG1 | c.1856T>C p.V619A | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ITGAM | c.1407C>A p.N469K | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- ITK | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 63/538 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- IVL | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); called by muse, varscan2
- JPH2 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KALRN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/292 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2
- KALRN | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 29/452 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNH6 | c.2920C>A p.P974T | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- KCNQ2 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNU1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- KDM4D | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KDM6A | c.1639C>G p.L547V | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA1210 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIAA1217 | c.4062G>T p.E1354D | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIAA1549 | c.1917_1918del p.S640Afs*14 | Frame Shift Del (DEL) | VAF 32/236 reads (14%) | called by mutect2, pindel, varscan2
- KIAA1549L | c.1630G>T p.A544S (on ENST00000321505; = p.A841S on NM_012194.3) | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF14 | c.3794A>G p.D1265G | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KLF14 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 37/327 reads (11%) | called by muse, mutect2, varscan2
- KLHL33 | c.1448T>A p.L483H | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KRTAP20-1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 16/245 reads (7%) | PolyPhen benign (0.23); called by muse, mutect2
- L3MBTL3 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- LAMA1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMA5 | c.2817_2819dup p.A939_M940insI | In Frame Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- LCT | c.3764G>A p.R1255K | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIPG | c.715A>T p.I239F | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LPA | c.3368G>T p.W1123L | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- LPCAT4 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- LPIN2 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN2 | c.1832T>A p.F611Y | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2
- LRFN5 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- LRP12 | c.1074A>T p.K358N | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP1B | c.3416C>A p.P1139H | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4 | c.1182C>A p.H394Q | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC47 | c.1311-1G>T p.X437_splice | Splice Site (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- LRRC55 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.797); called by muse, mutect2
- LRRC9 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LY6H | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.983); called by muse, varscan2
- MAGEB6B | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGEB6B | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MAGI1 | c.3896G>T p.R1299L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- MAN2B1 | c.2641C>T p.L881F | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP3K21 | c.986+1G>T p.X329_splice | Splice Site (SNP) | VAF 40/233 reads (17%) | called by muse, mutect2, varscan2
- MAST1 | c.4040C>A p.P1347H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MATK | c.370C>A p.H124N (on ENST00000310132 / NM_139355.3; = p.H125N on NM_002378.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD4 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- MC2R | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- MED1 | c.1073A>T p.N358I | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MGAM2 | c.3683C>A p.P1228H | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.5239C>A p.P1747T | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2
- MPP7 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- MPPED1 | c.837A>T p.L279F | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MRPS9 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MUC6 | c.4574T>A p.L1525Q | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.243); called by muse, varscan2
- MXRA5 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYBPC2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- MYH13 | c.3690G>T p.M1230I | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- MYO15B | c.4416G>T p.L1472F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MYO5A | c.1864G>T p.G622C | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- NAGA | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- NALCN | c.4537A>T p.K1513* | Nonsense Mutation (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- NAV3 | c.1753G>T p.G585* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- NBEAL2 | c.3145G>T p.V1049F | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- NCOA3 | c.749C>A p.A250E | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- NEFM | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- NES | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NEXMIF | c.2842G>T p.V948F | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- NIPAL1 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- NKX3-2 | c.761T>A p.F254Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP5 | c.2909T>A p.L970Q | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- NLRP9 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- NPAS1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAS4 | c.1503G>T p.L501F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NPHS1 | c.1214T>A p.L405Q | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.636); called by muse, mutect2
- NR5A2 | c.1534C>A p.Q512K (on ENST00000367362 / NM_205860.3; = p.Q466K on NM_003822.5) | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NRXN1 | c.4043C>A p.T1348K | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OBSCN | c.13468G>T p.A4490S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- OMA1 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1Q1 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2A5 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2
- OR2T10 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D6 | c.845T>A p.L282Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR5K1 | c.774G>C p.M258I | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5T3 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 61/539 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- OR8I2 | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSTF1 | c.494G>T p.R165I | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OTOF | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 40/211 reads (19%) | called by muse, mutect2, varscan2
- PADI3 | c.1904C>A p.T635N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PATE3 | c.150C>G p.C50W | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAX1 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PAX4 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBX3 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDH11X | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDH11X | c.1771C>G p.L591V | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PCDHB13 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 37/394 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCLO | c.13126G>C p.A4376P | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- PCSK5 | c.4974C>A p.Y1658* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- PDE4A | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDE6A | c.2245del p.E749Sfs*12 | Frame Shift Del (DEL) | VAF 39/354 reads (11%) | called by mutect2, pindel, varscan2
- PDGFRA | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); called by muse, mutect2
- PDZRN4 | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PGBD1 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PGBD1 | c.2009A>T p.K670M | Missense Mutation (SNP) | VAF 112/547 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, varscan2
- PIK3CG | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLAAT5 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLCB1 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLCE1 | c.3731G>T p.C1244F | Missense Mutation (SNP) | VAF 63/572 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PLEK | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PLXNA3 | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- POLQ | c.5721G>T p.W1907C | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POTEE | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- PPM1D | c.709A>G p.N237D | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PPP1R9B | c.1465G>T p.V489L | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PPP5C | c.869A>T p.K290M | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PRB4 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRG3 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- PROK2 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRSS1 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 80/582 reads (14%) | called by muse, varscan2
- PRSS56 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PRTG | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PSMD12 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.048); called by muse, mutect2
- PTHLH | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRT | c.3053C>G p.T1018R | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRT | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.2619dup p.A874Cfs*5 | Frame Shift Ins (INS) | VAF 54/384 reads (14%) | called by mutect2, pindel, varscan2
- RACK1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2
- RASGRF2 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 58/472 reads (12%) | called by muse, varscan2
- RAX | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- RBM19 | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- RBM20 | c.2140C>A p.H714N | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2
- RECQL4 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- REV1 | c.1322-2A>T p.X441_splice | Splice Site (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- RGS7 | c.1155G>T p.W385C | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF150 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RNF213 | c.11699A>C p.E3900A | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ROBO4 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RRBP1 | c.4003G>T p.A1335S (on ENST00000377813 / NM_001365613.2; = p.A902S on NM_004587.3) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RTN1 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2
- RYR2 | c.11335G>T p.D3779Y | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- RYR3 | c.4466G>T p.R1489L | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SALL2 | c.2471A>G p.E824G | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEM1 | c.171-2A>G p.X57_splice | Splice Site (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2
- SEMA3E | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 56/616 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- SEMA5A | c.1237A>G p.R413G | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SENP1 | c.1536G>T p.W512C | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEPTIN14 | c.774A>T p.K258N | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SHISA9 | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 22/311 reads (7%) | called by muse, mutect2
- SHLD2 | c.1317C>G p.S439R | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); called by muse, mutect2
- SHPRH | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SIDT1 | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- SLC10A2 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, varscan2
- SLC17A3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 46/592 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2
- SLC17A6 | c.972G>T p.W324C | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC26A7 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC27A6 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 39/320 reads (12%) | called by muse, mutect2, varscan2
- SLC35F5 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by mutect2, varscan2
- SLC5A1 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SLCO2B1 | c.1887G>T p.W629C | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMG8 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SOX4 | c.1096_1123del p.A366Pfs*34 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel
- SPAG5 | c.52-1G>T p.X18_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- SPANXN1 | c.48del p.C17Vfs*18 | Frame Shift Del (DEL) | VAF 28/236 reads (12%) | called by pindel, varscan2
- SPATA18 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SPEG | c.9728del p.G3243Afs*52 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | called by mutect2, pindel, varscan2
- SSTR5 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ST8SIA6 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ST8SIA6 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- STRN3 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- SUCNR1 | c.262T>A p.W88R | Missense Mutation (SNP) | VAF 30/465 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SUN3 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- SURF1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- SV2C | c.2021G>T p.C674F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- SVIL | c.5380G>T p.G1794* (on ENST00000355867 / NM_021738.3; = p.G1368* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- SYNCRIP | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SYNGR4 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TAS2R30 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TBC1D17 | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TBC1D2 | c.2612A>T p.N871I (on ENST00000465784 / NM_001267571.2; = p.N860I on NM_018421.4) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D5 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 38/290 reads (13%) | called by muse, mutect2, varscan2
- TENM1 | c.7381C>G p.R2461G | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.1987C>A p.L663M | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); called by muse, varscan2
- TGM2 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- TGM6 | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- THEM6 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TICRR | c.3094G>T p.V1032L | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- TMEM132B | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM132C | c.1884C>G p.D628E | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMEM132C | c.2333C>A p.A778D | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.576); called by muse, mutect2
- TMEM135 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TMEM185A | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 46/626 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TMEM71 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- TMPRSS3 | c.94+1G>T p.X32_splice | Splice Site (SNP) | VAF 26/524 reads (5%) | called by muse, mutect2
- TMTC1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPAZ1 | c.3436+1G>T p.X1146_splice | Splice Site (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- TOX3 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- TRAPPC8 | c.4051G>T p.D1351Y | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- TRHDE | c.2720T>A p.L907Q | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM10 | c.208del p.R70Gfs*84 | Frame Shift Del (DEL) | VAF 82/365 reads (22%) | called by mutect2, pindel, varscan2
- TRIM51 | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 74/715 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM51 | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 75/722 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.2481del p.A828Lfs*17 | Frame Shift Del (DEL) | VAF 36/296 reads (12%) | called by mutect2, pindel, varscan2
- TRPC1 | c.1096C>T p.L366F (on ENST00000476941 / NM_001251845.2; = p.L332F on NM_003304.4) | Missense Mutation (SNP) | VAF 107/596 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- TRPM4 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TRPM8 | c.3259A>T p.T1087S | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC1 | c.3104del p.G1035Vfs*56 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- TTN | c.13813A>T p.S4605C (on ENST00000591111; = p.S3678C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/334 reads (21%) | PolyPhen benign (0.386); called by muse, mutect2, varscan2
- UCP1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 32/463 reads (7%) | called by muse, mutect2
- UMODL1 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC79 | c.5296G>T p.D1766Y (on ENST00000393151 / NM_001346218.2; = p.D1589Y on NM_020818.5) | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.6841C>A p.L2281I (on ENST00000393151 / NM_001346218.2; = p.L2104I on NM_020818.5) | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- USH2A | c.11414T>A p.V3805E | Missense Mutation (SNP) | VAF 80/462 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); called by muse, varscan2
- USH2A | c.7283T>G p.I2428S | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- USP40 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 82/415 reads (20%) | called by muse, mutect2, varscan2
- VASN | c.1651G>T p.G551W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VN1R4 | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.013); called by muse, mutect2
- VOPP1 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- VWA5B1 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VWF | c.5086C>A p.L1696M | Missense Mutation (SNP) | VAF 131/631 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.6298G>T p.D2100Y | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, varscan2
- WDR41 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- WT1 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 55/461 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWC2 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- ZAN | c.1055dup p.E353Rfs*7 | Frame Shift Ins (INS) | VAF 25/216 reads (12%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2034_2035dup p.K679Ifs*22 | Frame Shift Ins (INS) | VAF 38/384 reads (10%) | called by mutect2, pindel
- ZCCHC8 | c.671+5G>T | Splice Region (SNP) | VAF 43/287 reads (15%) | called by muse, mutect2, varscan2
- ZFHX3 | c.5396C>A p.P1799H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZIC3 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZIM3 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ZNF134 | c.-57-1G>T | Splice Site (SNP) | VAF 34/290 reads (12%) | called by muse, mutect2, varscan2
- ZNF257 | c.948del p.Y316* | Frame Shift Del (DEL) | VAF 40/331 reads (12%) | called by mutect2, pindel, varscan2
- ZNF407 | c.5663C>T p.A1888V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ZNF469 | c.11542G>A p.E3848K (on ENST00000437464; = p.E3876K on NM_001367624.2) | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- ZNF490 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- ZNF583 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF615 | c.1442A>G p.E481G | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF655 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 56/379 reads (15%) | called by muse, mutect2, varscan2
- ZNF716 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF804A | c.2482C>G p.L828V | Missense Mutation (SNP) | VAF 78/449 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 54/636 reads (8%) | called by muse, mutect2
- ZYX | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACSL6 | c.387G>A p.R129= (on ENST00000379240; = p.R154= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- AP3M2 | c.930C>T p.V310= | Silent (SNP) | VAF 28/326 reads (9%) | catalogued as rs775824076; called by muse, mutect2
- ARGFX | c.192C>A p.T64= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ARID3C | c.444C>T p.Y148= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99426869; called by muse, mutect2, varscan2
- ARID4A | c.144A>T p.T48= | Silent (SNP) | VAF 31/342 reads (9%) | called by muse, mutect2
- ATXN7L1 | c.2181G>T p.A727= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- AXL | c.2457C>T p.I819= (on ENST00000301178 / NM_021913.5; = p.I810= on NM_001699.6) | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as COSV56575483; called by muse, mutect2, varscan2
- BCAN | c.1263A>T p.P421= | Silent (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- BCAR1 | c.1851G>T p.G617= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs199823639; called by muse, mutect2, varscan2
- BHLHA15 | c.483G>A p.G161= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- BIRC2 | c.888T>C p.Y296= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs1013417344; called by muse, mutect2, varscan2
- BRAF | c.786A>G p.Q262= | Silent (SNP) | VAF 83/628 reads (13%) | called by muse, mutect2, varscan2
- C19orf81 | c.174C>T p.Y58= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs984316344; called by muse, mutect2, varscan2
- C21orf91 | c.712C>T p.L238= | Silent (SNP) | VAF 42/624 reads (7%) | called by muse, mutect2
- C4orf54 | c.2352G>T p.T784= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- CACNA1C | c.2112C>A p.T704= | Silent (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- CACNA1C | c.4044G>C p.T1348= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- CASQ2 | c.576C>T p.Y192= | Silent (SNP) | VAF 45/290 reads (16%) | catalogued as rs758748280; called by muse, mutect2, varscan2
- CBR1 | c.573C>T p.S191= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CCDC170 | c.507G>A p.E169= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV53347341; called by muse, mutect2
- CCDC198 | c.834G>A p.L278= | Silent (SNP) | VAF 37/353 reads (10%) | called by muse, mutect2, varscan2
- CCDC33 | c.513G>T p.R171= | Silent (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- CCNE1 | c.804G>T p.P268= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- CCR6 | c.726G>T p.V242= | Silent (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- CD99L2 | c.36C>T p.L12= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- CDCP2 | c.1293G>T p.L431= | Silent (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- CDH9 | c.1758C>T p.I586= | Silent (SNP) | VAF 86/624 reads (14%) | catalogued as COSV50279128; called by muse, varscan2
- CFAP57 | c.3573C>T p.T1191= (on ENST00000372492 / NM_001378189.1; = p.T1224= on NM_001195831.3) | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as rs1006282371; called by muse, varscan2
- CGB1 | c.111G>A p.E37= | Silent (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- CLCN1 | c.2829C>G p.A943= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- CLCNKB | c.72C>A p.P24= | Silent (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- CMSS1 | c.51A>T p.A17= | Silent (SNP) | VAF 16/283 reads (6%) | called by muse, mutect2
- CNTNAP4 | c.2445G>T p.A815= | Silent (SNP) | VAF 55/386 reads (14%) | catalogued as COSV56697688; called by mutect2, varscan2
- CNTNAP5 | c.1818C>A p.I606= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- COL5A3 | c.3369G>T p.R1123= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- COL6A5 | c.3516G>T p.V1172= | Silent (SNP) | VAF 43/338 reads (13%) | catalogued as COSV55217597; called by muse, mutect2, varscan2
- CRACD | c.2748C>A p.T916= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV51727634; called by muse, mutect2, varscan2
- CSMD3 | c.8751C>A p.A2917= (on ENST00000297405 / NM_001363185.1; = p.A2748= on NM_052900.3) | Silent (SNP) | VAF 63/448 reads (14%) | called by muse, mutect2, varscan2
- CSTF3 | c.1308G>T p.G436= | Silent (SNP) | VAF 32/403 reads (8%) | called by muse, mutect2
- CYP2F1 | c.234C>T p.L78= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1313969504; called by muse, varscan2
- DCC | c.1020G>T p.L340= | Silent (SNP) | VAF 87/702 reads (12%) | called by muse, varscan2
- DDI1 | c.912A>T p.L304= | Silent (SNP) | VAF 43/406 reads (11%) | called by muse, mutect2, varscan2
- DLX6 | c.801C>A p.P267= | Silent (SNP) | VAF 24/359 reads (7%) | called by muse, mutect2
- DNM1L | c.924A>T p.I308= | Silent (SNP) | VAF 112/540 reads (21%) | called by muse, mutect2, varscan2
- DSCAM | c.2937G>C p.A979= | Silent (SNP) | VAF 23/361 reads (6%) | catalogued as COSV68027706; called by muse, mutect2
- DSCAM | c.1620C>T p.N540= | Silent (SNP) | VAF 48/524 reads (9%) | catalogued as rs1373955585; called by muse, mutect2
- EBF1 | c.615A>G p.P205= | Silent (SNP) | VAF 31/296 reads (10%) | called by muse, mutect2, varscan2
- ELMO1 | c.588G>T p.S196= | Silent (SNP) | VAF 34/263 reads (13%) | catalogued as COSV60299505, COSV60302268; called by muse, mutect2, varscan2
- EMILIN2 | c.1260T>A p.A420= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- ENTPD2 | c.909G>T p.G303= | Silent (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- EPHB1 | c.2733G>C p.T911= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV67673515; called by muse, mutect2, varscan2
- EXOSC7 | c.201G>T p.G67= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- FAM171B | c.429C>T p.G143= | Silent (SNP) | VAF 67/255 reads (26%) | called by muse, mutect2, varscan2
- FBXL13 | c.819C>T p.V273= | Silent (SNP) | VAF 37/324 reads (11%) | called by muse, mutect2, varscan2
- FLT1 | c.1524C>A p.R508= | Silent (SNP) | VAF 63/524 reads (12%) | called by muse, varscan2
- FZD4 | c.1221T>A p.A407= | Silent (SNP) | VAF 131/983 reads (13%) | called by muse, mutect2, varscan2
- GRK5 | c.282A>C p.P94= | Silent (SNP) | VAF 24/315 reads (8%) | called by muse, mutect2
- GRM8 | c.1716C>A p.I572= | Silent (SNP) | VAF 45/266 reads (17%) | catalogued as COSV100285097; called by muse, mutect2, varscan2
- HDAC9 | c.666C>A p.P222= | Silent (SNP) | VAF 43/513 reads (8%) | called by muse, mutect2
- HEPACAM | c.771G>T p.V257= | Silent (SNP) | VAF 70/598 reads (12%) | called by muse, mutect2, varscan2
- HPCAL4 | c.27C>A p.A9= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs754103411; called by muse, mutect2, varscan2
- HSCB | c.399C>A p.A133= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- HSD17B14 | c.174T>C p.F58= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- HTR1E | c.435C>A p.T145= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV59506510; called by muse, mutect2, varscan2
- IL18R1 | c.1566A>C p.A522= | Silent (SNP) | VAF 40/177 reads (23%) | called by muse, mutect2, varscan2
- IL21R | c.1206G>A p.L402= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- IL5RA | c.336C>T p.S112= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs1206209416, COSV56520761; called by muse, mutect2
- INPP5F | c.2679T>A p.G893= | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as COSV62822684; called by muse, mutect2
- ITGA10 | c.1576C>T p.L526= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV65196245; called by muse, mutect2, varscan2
- ITGAM | c.1932G>T p.V644= (on ENST00000648685 / NM_001145808.2; = p.V643= on NM_000632.4) | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as COSV54940704; called by muse, mutect2, varscan2
- KCNA10 | c.1065G>T p.S355= | Silent (SNP) | VAF 58/307 reads (19%) | catalogued as COSV63904206; called by muse, mutect2, varscan2
- KCNK3 | c.417G>C p.L139= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- KCTD7 | c.756G>T p.G252= (on ENST00000275532; = p.V266L on NM_153033.5) | Silent (SNP) | VAF 35/221 reads (16%) | catalogued as rs1297799073, COSV51876403, COSV99299110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF3C | c.1212C>A p.P404= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- KLHL13 | c.72C>A p.A24= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- KLHL18 | c.1515C>T p.C505= | Silent (SNP) | VAF 20/317 reads (6%) | called by muse, mutect2
- KRT5 | c.60C>T p.A20= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs771067613; called by muse, mutect2, varscan2
- KRTAP9-4 | c.426C>A p.P142= | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2
- LFNG | c.1005T>A p.G335= (on ENST00000222725 / NM_001040167.2; = p.G206= on NM_002304.2) | Silent (SNP) | VAF 31/256 reads (12%) | called by muse, mutect2, varscan2
- LILRB2 | c.1179C>T p.T393= | Silent (SNP) | VAF 80/469 reads (17%) | called by muse, varscan2
- LILRB2 | c.1083A>T p.A361= | Silent (SNP) | VAF 82/520 reads (16%) | called by muse, varscan2
- LRP1B | c.13335C>A p.A4445= | Silent (SNP) | VAF 70/351 reads (20%) | called by muse, mutect2, varscan2
- LTBP2 | c.1539C>A p.P513= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- LUM | c.969G>T p.P323= | Silent (SNP) | VAF 46/432 reads (11%) | called by muse, mutect2, varscan2
- M1AP | c.777G>T p.L259= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, varscan2
- MAGEA10 | c.891G>T p.L297= | Silent (SNP) | VAF 24/187 reads (13%) | called by muse, mutect2, varscan2
- MAP7D1 | c.213C>A p.P71= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, varscan2
- MARK4 | c.1791G>T p.L597= | Silent (SNP) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- MDGA2 | c.2895A>G p.E965= (on ENST00000399232 / NM_001113498.2; = p.E667= on NM_182830.4) | Silent (SNP) | VAF 54/502 reads (11%) | catalogued as COSV100638861; called by muse, mutect2, varscan2
- MGAM2 | c.3684C>G p.P1228= | Silent (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- MOV10L1 | c.351C>A p.P117= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99434287; called by muse, mutect2
- MPPED2 | c.81G>T p.T27= | Silent (SNP) | VAF 32/352 reads (9%) | catalogued as COSV63898154; called by muse, mutect2
- MS4A14 | c.1056T>C p.A352= | Silent (SNP) | VAF 33/319 reads (10%) | called by muse, mutect2, varscan2
- MSH4 | c.1143A>G p.L381= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs1200034902; called by muse, mutect2
- MUC5AC | c.15093C>T p.T5031= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- MYL7 | c.156C>A p.I52= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- MYO5A | c.2448G>A p.K816= | Silent (SNP) | VAF 37/720 reads (5%) | called by muse, mutect2
- MYOZ2 | c.126C>A p.I42= | Silent (SNP) | VAF 72/474 reads (15%) | catalogued as COSV61085039; called by muse, mutect2, varscan2
- NAP1L3 | c.1035G>T p.L345= | Silent (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- NELL1 | c.264C>A p.T88= | Silent (SNP) | VAF 24/255 reads (9%) | catalogued as COSV54296594; called by muse, mutect2, varscan2
- NHLRC2 | c.942A>T p.V314= | Silent (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- OBSCN | c.3669G>T p.L1223= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- OR10C1 | c.420G>T p.R140= (on ENST00000622521; = p.R138= on NM_013941.3) | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV65822942; called by muse, mutect2
- OR4B1 | c.366G>A p.V122= | Silent (SNP) | VAF 19/254 reads (7%) | called by muse, mutect2
- OR6K3 | c.522C>A p.P174= (on ENST00000368146; = p.P158= on NM_001005327.2) | Silent (SNP) | VAF 41/254 reads (16%) | catalogued as rs149886388, COSV63745307; called by muse, mutect2, varscan2
- OTOF | c.2689C>A p.R897= (on ENST00000272371 / NM_194248.3; = p.R150= on NM_004802.4) | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV55499483; called by muse, mutect2, varscan2
- PCDH15 | c.5274T>C p.P1758= | Silent (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- PCDH18 | c.1746T>C p.R582= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- PCDHB13 | c.2247C>T p.Y749= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as rs1385676872, COSV53393440; called by muse, mutect2, varscan2
- PCDHGA1 | c.198C>A p.I66= | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1689G>C p.L563= | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- PCSK5 | c.2562A>C p.T854= | Silent (SNP) | VAF 43/368 reads (12%) | catalogued as rs757935315; called by muse, mutect2, varscan2
- PDE2A | c.201C>A p.V67= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- PDE3A | c.2815C>T p.L939= | Silent (SNP) | VAF 54/272 reads (20%) | catalogued as COSV62976252; called by muse, mutect2, varscan2
- PDZRN3 | c.675G>T p.A225= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PGR | c.2769G>A p.G923= | Silent (SNP) | VAF 66/539 reads (12%) | catalogued as rs868582452; called by muse, mutect2, varscan2
- PLCD3 | c.1266C>A p.S422= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59561371; called by muse, varscan2
- PLCL1 | c.1038C>T p.T346= | Silent (SNP) | VAF 81/386 reads (21%) | called by muse, mutect2, varscan2
- PLXNA2 | c.558G>C p.T186= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as COSV65444170; called by muse, mutect2, varscan2
- PPIG | c.936A>T p.P312= | Silent (SNP) | VAF 81/464 reads (17%) | called by muse, mutect2, varscan2
- PRKN | c.105G>T p.G35= | Silent (SNP) | VAF 26/200 reads (13%) | called by muse, mutect2, varscan2
- PSG3 | c.975C>A p.T325= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- PTPRB | c.744G>C p.V248= | Silent (SNP) | VAF 35/524 reads (7%) | called by muse, mutect2
- PTPRZ1 | c.4590G>T p.L1530= | Silent (SNP) | VAF 49/268 reads (18%) | called by muse, mutect2, varscan2
- RALGAPB | c.2898G>A p.E966= | Silent (SNP) | VAF 39/256 reads (15%) | called by muse, mutect2, varscan2
- RALYL | c.555G>T p.G185= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs368121390; called by muse, mutect2, varscan2
- RASAL2 | c.2619G>T p.V873= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV62712603; called by muse, mutect2
- RSPH14 | c.462G>T p.L154= | Silent (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- RXFP3 | c.1233G>A p.S411= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV57507532; called by muse, mutect2
- RYR1 | c.1764C>A p.L588= | Silent (SNP) | VAF 64/514 reads (12%) | catalogued as COSV62102207; called by muse, mutect2, varscan2
- RYR2 | c.4203T>C p.H1401= | Silent (SNP) | VAF 48/348 reads (14%) | called by muse, mutect2, varscan2
- S100A14 | c.6A>T p.G2= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- SALL1 | c.615G>T p.V205= | Silent (SNP) | VAF 33/311 reads (11%) | called by muse, mutect2, varscan2
- SEMA3B | c.2229G>T p.P743= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57114714; called by muse, mutect2, varscan2
- SLC10A2 | c.195G>T p.P65= | Silent (SNP) | VAF 29/214 reads (14%) | catalogued as rs200026503, COSV55360142; called by muse, varscan2
- SLC34A1 | c.663G>T p.T221= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SP8 | c.1326C>A p.G442= (on ENST00000361443 / NM_198956.4; = p.G460= on NM_182700.6) | Silent (SNP) | VAF 32/189 reads (17%) | called by muse, varscan2
- SPPL2C | c.213G>A p.P71= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs954825666; called by muse, mutect2
- SPTA1 | c.6750G>A p.L2250= | Silent (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- SRRM3 | c.801C>A p.S267= | Silent (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- STK36 | c.3114A>G p.T1038= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- SYNGR4 | c.687T>A p.A229= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- TAS2R1 | c.240G>T p.A80= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as COSV66778817, COSV66779009; called by muse, mutect2, varscan2
- TBC1D23 | c.1476G>T p.V492= | Silent (SNP) | VAF 21/384 reads (5%) | called by muse, mutect2
- TENM1 | c.1077T>C p.N359= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- TENM3 | c.6369C>A p.A2123= | Silent (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- TENT5A | c.1161G>T p.R387= | Silent (SNP) | VAF 37/253 reads (15%) | called by muse, mutect2, varscan2
- TFAP2D | c.159C>A p.T53= | Silent (SNP) | VAF 45/405 reads (11%) | catalogued as rs780621262; called by muse, mutect2, varscan2
- TMEM225 | c.357A>G p.L119= | Silent (SNP) | VAF 23/200 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.144G>T p.G48= | Silent (SNP) | VAF 33/446 reads (7%) | catalogued as rs568954917; called by muse, mutect2
- TNNT1 | c.528G>A p.Q176= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as COSV52570814; called by muse, mutect2, varscan2
- TOX3 | c.1662T>A p.S554= | Silent (SNP) | VAF 44/452 reads (10%) | called by muse, mutect2
- TRAPPC9 | c.1263G>T p.A421= | Silent (SNP) | VAF 32/343 reads (9%) | catalogued as COSV101226783; called by muse, mutect2
- TRAV27 | c.6C>A p.V2= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- TRIL | c.570G>T p.R190= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- UGT2B17 | c.1011A>C p.L337= | Silent (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- UGT2B7 | c.984G>C p.L328= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV59445264; called by muse, varscan2
- USH2A | c.288C>A p.T96= | Silent (SNP) | VAF 16/478 reads (3%) | called by muse, mutect2
- USP19 | c.2529G>T p.L843= | Silent (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- VAV3 | c.849T>C p.S283= | Silent (SNP) | VAF 91/554 reads (16%) | catalogued as COSV58376955; called by muse, mutect2, varscan2
- WDR44 | c.1572A>T p.R524= | Silent (SNP) | VAF 43/322 reads (13%) | called by muse, mutect2, varscan2
- WDR90 | c.2331G>C p.L777= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- WHRN | c.1518G>T p.R506= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- ZCCHC8 | c.459G>T p.V153= | Silent (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- ZNF48 | c.1422A>G p.T474= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs769534439; called by muse, mutect2, varscan2
- A2M | c.4408+11C>A | Intron (SNP) | VAF 71/310 reads (23%) | called by muse, mutect2, varscan2
- ABCC8 | c.3868-19A>T | Intron (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- AC006486.1 | c.23-2802C>A | Intron (SNP) | VAF 35/242 reads (14%) | called by muse, mutect2, varscan2
- AC011410.1 | n.567G>T | RNA (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- ACER3 | c.215-1490G>T | Intron (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- ADAMTS2 | c.1629+1057G>T | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, varscan2
- AGAP14P | n.911C>A | RNA (SNP) | VAF 21/508 reads (4%) | called by muse, mutect2
- AGAP7P | n.1224C>G | RNA (SNP) | VAF 50/587 reads (9%) | called by muse, mutect2, varscan2
73 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 73 other) are not listed here.
